Somatic mutation profile of tumor specimen ALCH-B2OP-TTP1-A (aliquot ALCH-B2OP-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2OP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,184 days).
Specimen ALCH-B2OP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c04d1ad1-2310-4a68-b0f1-d183509bd55c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OP-NB1-A (Blood Derived Normal), aliquot ALCH-B2OP-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f13b2ed6-c9e7-45ac-b18b-6ba96a69ebc9

The open-access MAF lists 193 somatic variants for this specimen: 144 protein-altering or splice-affecting, 28 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Silent 28, Intron 15, Nonsense Mutation 9, Frame Shift Del 8, Splice Site 6, Frame Shift Ins 4, 3'UTR 2, Splice Region 2, RNA 2, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.157dup p.D53Gfs*110 | Frame Shift Ins (INS) | VAF 32/150 reads (21%) | catalogued as rs1131690917; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.1024del p.R342Efs*3 | Frame Shift Del (DEL) | VAF 31/209 reads (15%) | catalogued as rs1131691022, CM004908, COSV52665487; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD30A | c.3676G>T p.A1226S (on ENST00000611781; = p.A1170S on NM_052997.2) | Missense Mutation (SNP) | VAF 37/271 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs767880599; called by muse, mutect2, varscan2
- ASIC2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV56761153, COSV56762249; called by muse, mutect2, varscan2
- C1orf94 | c.1219G>A p.G407R (on ENST00000488417 / NM_001134734.2; = p.G217R on NM_032884.5) | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.062); catalogued as rs142411412; called by muse, mutect2, varscan2
- CDH22 | c.1666A>T p.N556Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV64839993; called by muse, mutect2
- CDH9 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50253534, COSV99141291; called by muse, mutect2
- CTNNA2 | c.376del p.A126Rfs*9 | Frame Shift Del (DEL) | VAF 36/263 reads (14%) | catalogued as COSV63582509; called by mutect2, pindel, varscan2
- CXorf66 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as COSV65169481; called by muse, mutect2, varscan2
- DPYS | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs1186704630; called by muse, mutect2, varscan2
- FAM13C | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as COSV53247128; called by muse, mutect2, varscan2
- FRMD8 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV58214207; called by muse, mutect2
- GIGYF1 | c.1636A>G p.M546V | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as rs746104166; called by muse, mutect2, varscan2
- HEATR5B | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198042837, COSV99248852; called by muse, mutect2, varscan2
- HGF | c.1940G>A p.R647Q | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1267493094, COSV55945259; called by muse, mutect2, varscan2
- HSD17B6 | c.607A>G p.I203V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs765771878; called by muse, mutect2, varscan2
- KEAP1 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV50601743; called by muse, mutect2, varscan2
- KLHL13 | c.1217C>T p.T406M | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1322653209, COSV99450736; called by muse, mutect2, varscan2
- KLHL41 | c.1710-1G>C p.X570_splice | Splice Site (SNP) | VAF 28/143 reads (20%) | catalogued as rs112795676; called by muse, mutect2, varscan2
- KRTAP5-2 | c.320del p.G107Afs*85 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as rs1432537257; called by mutect2, varscan2
- LRRTM4 | c.1120G>C p.V374L | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs770128588, COSV69142566; called by muse, mutect2, varscan2
- MAJIN | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV57262160; called by muse, mutect2, varscan2
- MCM3AP | c.5512G>C p.E1838Q | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.157); catalogued as rs771411919, COSV99387016; called by muse, mutect2, varscan2
- MT1G | c.12C>A p.N4K | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated, low confidence (0.07); catalogued as rs749764712; called by muse, mutect2, varscan2
- MUC16 | c.13994G>A p.R4665K | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs756205989; called by muse, mutect2, varscan2
- MYRFL | c.2056T>A p.S686T | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1483468459; called by muse, mutect2
- NRG1 | c.1190G>T p.G397V (on ENST00000405005 / NM_013964.5; = p.G402V on NM_013956.5) | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV55164496; called by muse, mutect2, varscan2
- NTNG1 | c.712C>G p.R238G | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.529); catalogued as COSV53977286; called by muse, mutect2, varscan2
- NTNG2 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62366611; called by muse, mutect2, varscan2
- OR2T8 | c.888G>C p.K296N | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.613); catalogued as rs151007478, COSV60664653; called by muse, mutect2
- OR9A4 | c.413G>T p.R138I | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV101516324, COSV71885127; called by muse, mutect2, varscan2
- PCDHGA11 | c.557G>T p.R186I | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.041); catalogued as COSV53891955, COSV54048929; called by muse, mutect2, varscan2
- PPP4R3C | c.776T>C p.L259P | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101297303; called by muse, mutect2
- PXDNL | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62486551; called by muse, mutect2, varscan2
- ST6GAL2 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 12/57 reads (21%) | PolyPhen probably damaging (0.986); catalogued as rs773859154; called by muse, mutect2
- TEX37 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV100304680; called by muse, mutect2, varscan2
- TRIP11 | c.4601C>G p.S1534* | Nonsense Mutation (SNP) | VAF 97/552 reads (18%) | catalogued as COSV50928799; called by muse, mutect2, varscan2
- URB1 | c.1640A>G p.D547G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1016520746; called by muse, mutect2, varscan2
- VPS9D1 | c.1598-1G>A p.X533_splice | Splice Site (SNP) | VAF 27/157 reads (17%) | catalogued as rs1410313531; called by muse, varscan2
- ZFHX4 | c.10252G>T p.A3418S | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs374431158; called by muse, mutect2, varscan2
- ZNF251 | c.1600G>A p.D534N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1201859808; called by muse, varscan2
- ZP4 | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.049); catalogued as rs1295671900, COSV63912308; called by muse, varscan2
- ZUP1 | c.245A>C p.Q82P | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs772025903; called by muse, mutect2, varscan2
- ACACA | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- ADAMTS12 | c.2846C>A p.T949K | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ADGRG4 | c.3928C>A p.H1310N | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AHNAK2 | c.11467G>A p.E3823K | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AK5 | c.768G>T p.K256N (on ENST00000354567 / NM_174858.3; = p.K230N on NM_012093.4) | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP9 | c.2461G>T p.E821* | Nonsense Mutation (SNP) | VAF 16/90 reads (18%) | called by muse, varscan2
- ALMS1 | c.3507G>C p.Q1169H | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ALPK1 | c.2672C>G p.S891C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APOBEC1 | c.126_136del p.K43Efs*19 | Frame Shift Del (DEL) | VAF 14/140 reads (10%) | called by mutect2, pindel
- ARL14 | c.170_191del p.N57Mfs*8 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by pindel, varscan2
- ARL14 | c.194T>A p.V65D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- ATAD2B | c.1898A>G p.Y633C | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD7 | c.1546_1549del p.L516Yfs*12 | Frame Shift Del (DEL) | VAF 27/202 reads (13%) | called by mutect2, pindel*, varscan2*
- CD5L | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- CDH12 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP41 | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CFAP61 | c.3483dup p.E1162Rfs*27 | Frame Shift Ins (INS) | VAF 30/190 reads (16%) | called by mutect2, pindel, varscan2
- CHRNB2 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A1 | c.4357-1G>A p.X1453_splice | Splice Site (SNP) | VAF 28/246 reads (11%) | called by mutect2, varscan2
- COL11A1 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 101/555 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- COQ6 | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CPE | c.899G>A p.C300Y | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- CPSF6 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 34/1041 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD1 | c.5905C>T p.P1969S (on ENST00000520002; = p.P1968S on NM_033225.6) | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CUL1 | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); called by muse, mutect2
- DACT3 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DLG5 | c.1946dup p.D651Gfs*8 | Frame Shift Ins (INS) | VAF 36/280 reads (13%) | called by mutect2, pindel, varscan2
- EEF1AKMT4-ECE2 | c.1527G>C p.W509C | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EGLN2 | c.805G>T p.G269W | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, varscan2
- ELAPOR2 | c.971T>G p.I324R (on ENST00000450689 / NM_001142749.3; = p.I157R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EMC4 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FABP2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM13A | c.832C>A p.P278T | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.051); called by muse, varscan2
- GFRA2 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- GLB1L2 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPI | c.862G>T p.V288L | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GSX2 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2
- GTF2IRD2B | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.027); called by mutect2, varscan2
- HAUS4 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- HHIPL2 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HIPK3 | c.332C>A p.A111E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSD3B2 | c.1034G>T p.W345L | Missense Mutation (SNP) | VAF 46/232 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA4L | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- IDI1 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- IGHV1-46 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 57/451 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- IRX6 | c.1325G>C p.G442A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- KREMEN2 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRP1B | c.3538A>T p.N1180Y | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LRRC9 | c.3318-5T>C | Splice Region (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2, varscan2
- LRRK1 | c.3168G>C p.R1056S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- MAB21L3 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- MACF1 | c.12353A>G p.Q4118R (on ENST00000372915; = p.Q2051R on NM_012090.5) | Missense Mutation (SNP) | VAF 60/361 reads (17%) | called by muse, mutect2, varscan2
- MAGEA12 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- MAGI2 | c.3457G>T p.G1153* | Nonsense Mutation (SNP) | VAF 44/238 reads (18%) | called by muse, mutect2, varscan2
- MCM3AP | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.583); called by muse, varscan2
- MMP16 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MSRB3 | c.266-1G>A p.X89_splice | Splice Site (SNP) | VAF 245/379 reads (65%) | called by muse, mutect2, varscan2
- MTMR8 | c.229T>G p.F77V | Missense Mutation (SNP) | VAF 6/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- NALCN | c.2996T>C p.L999P | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF12 | c.3496G>T p.D1166Y | Missense Mutation (SNP) | VAF 98/2106 reads (5%) | SIFT deleterious (0); called by muse, mutect2
- NIBAN3 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- OR2M3 | c.510del p.S171Lfs*4 | Frame Shift Del (DEL) | VAF 27/170 reads (16%) | called by mutect2, pindel, varscan2
- PADI6 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- PCDH7 | c.2443C>A p.H815N | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1L1 | c.1339A>G p.R447G | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2
- PLAG1 | c.559T>G p.C187G | Missense Mutation (SNP) | VAF 60/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLPPR5 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 68/472 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R12A | c.2778G>C p.K926N | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- REPIN1 | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RPS5 | c.410A>G p.Q137R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SFMBT2 | c.403A>G p.T135A | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SFRP2 | c.509dup p.V171Gfs*3 | Frame Shift Ins (INS) | VAF 10/102 reads (10%) | called by pindel, varscan2
- SH3TC2 | c.280-2A>T p.X94_splice | Splice Site (SNP) | VAF 50/257 reads (19%) | called by muse, mutect2, varscan2
- SHPRH | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIGLEC8 | c.1094G>C p.G365A | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.346); called by muse, mutect2
- SLC1A4 | c.573T>G p.Y191* | Nonsense Mutation (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- SLC44A1 | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SLC4A10 | c.3017C>T p.A1006V (on ENST00000446997 / NM_001354461.2; = p.A976V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/353 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLC6A18 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT3 | c.2882A>G p.Q961R | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SMTNL2 | c.539C>T p.P180L (on ENST00000389313 / NM_001114974.2; = p.P36L on NM_198501.3) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- SNRPA | c.396del p.V133Wfs*15 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- SNX11 | c.592A>T p.S198C | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- SRA1 | c.61+7G>T | Splice Region (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- STAT4 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- STK32C | c.338C>T p.P113L | Missense Mutation (SNP) | VAF 27/205 reads (13%) | PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TRIM32 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- TTN | c.76963G>C p.E25655Q (on ENST00000591111; = p.E18231Q on NM_003319.4) | Missense Mutation (SNP) | VAF 50/312 reads (16%) | PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- UNC5C | c.2513G>T p.G838V | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSIG4 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- WASHC2A | c.1181-1G>T p.X394_splice | Splice Site (SNP) | VAF 28/274 reads (10%) | called by muse, mutect2, varscan2
- WDR90 | c.4824G>T p.W1608C | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WRN | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- XIRP2 | c.4049C>A p.T1350N (on ENST00000628543; = p.T1525N on NM_152381.6) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- XIRP2 | c.7655A>G p.H2552R (on ENST00000628543; = p.H2727R on NM_152381.6) | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDHHC16 | c.156C>G p.N52K | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ZHX3 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ZNF679 | c.1115G>T p.R372M | Missense Mutation (SNP) | VAF 47/335 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF800 | c.1417A>T p.R473* | Nonsense Mutation (SNP) | VAF 45/296 reads (15%) | called by muse, mutect2, varscan2
- ZNF831 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- ZPBP | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALDH3B2 | c.183C>T p.I61= | Silent (SNP) | VAF 10/107 reads (9%) | called by muse, mutect2, varscan2
- ALPK3 | c.2133G>A p.Q711= | Silent (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- ASB2 | c.1032C>T p.R344= | Silent (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- C1orf87 | c.420C>T p.P140= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- DOCK3 | c.5658C>G p.S1886= | Silent (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- EXOC8 | c.1275G>C p.T425= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- FOXC1 | c.735C>A p.A245= | Silent (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- GPR65 | c.201C>A p.L67= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV50862591; called by muse, mutect2, varscan2
- IFFO2 | c.261G>A p.Q87= | Silent (SNP) | VAF 22/151 reads (15%) | called by muse, mutect2, varscan2
- IGFBP3 | c.84C>A p.G28= | Silent (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- INPP5B | c.1683G>A p.Q561= (on ENST00000373023; = p.Q481= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 46/212 reads (22%) | called by muse, mutect2, varscan2
- L1CAM | c.502C>A p.R168= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV104423519; called by muse, mutect2, varscan2
- NLRP12 | c.618C>T p.R206= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs1357903998; called by muse, mutect2, varscan2
- NOS2 | c.2664C>T p.S888= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- NPAP1 | c.2928A>C p.T976= | Silent (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- NRXN1 | c.3181C>A p.R1061= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV58471239; called by muse, mutect2, varscan2
- OR6F1 | c.864C>T p.F288= | Silent (SNP) | VAF 42/213 reads (20%) | catalogued as COSV57468277; called by muse, mutect2, varscan2
- POLRMT | c.2574G>T p.R858= | Silent (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.4272T>C p.D1424= | Silent (SNP) | VAF 13/75 reads (17%) | called by mutect2, varscan2
- RAB11FIP1 | c.1347C>A p.G449= | Silent (SNP) | VAF 50/343 reads (15%) | called by muse, mutect2, varscan2
- RPL10L | c.96C>A p.R32= | Silent (SNP) | VAF 38/252 reads (15%) | catalogued as rs1405946624, COSV53559750; called by muse, mutect2, varscan2
- SELENOT | c.24A>G p.L8= | Silent (SNP) | VAF 19/79 reads (24%) | called by muse, mutect2, varscan2
- SLX4IP | c.891G>A p.R297= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV57947225; called by muse, mutect2, varscan2
- TMTC1 | c.1680C>A p.S560= (on ENST00000539277 / NM_001193451.2; = p.S452= on NM_175861.3) | Silent (SNP) | VAF 44/512 reads (9%) | catalogued as COSV55486071; called by muse, mutect2
- TOGARAM1 | c.561G>T p.S187= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs1276836495; called by muse, mutect2, varscan2
- XIRP2 | c.4050C>A p.T1350= (on ENST00000628543; = p.T1525= on NM_152381.6) | Silent (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- ZNF10 | c.261A>T p.S87= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- ZNF446 | c.774G>C p.G258= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- CASC15 | chr6:22147169 C>T | 5'Flank (SNP) | VAF 60/164 reads (37%) | catalogued as rs1262364587; called by muse, mutect2, varscan2
- CNTNAP3P2 | n.1146C>T | RNA (SNP) | VAF 40/268 reads (15%) | called by muse, mutect2, varscan2
- COL1A2 | c.3267+46G>T | Intron (SNP) | VAF 26/186 reads (14%) | called by muse, mutect2, varscan2
- CPAMD8 | c.5567+359T>C | Intron (SNP) | VAF 3/12 reads (25%) | catalogued as rs1365048671; called by muse, mutect2
- CPLANE1 | c.*4033C>T | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2, varscan2
- EHD4 | c.511+58G>T | Intron (SNP) | VAF 14/55 reads (25%) | catalogued as rs1244458967; called by muse, mutect2
- ETV1 | c.45+260G>A | Intron (SNP) | VAF 82/362 reads (23%) | catalogued as rs780727008; called by muse, mutect2, varscan2
- FAM124A | c.101-6153G>C | Intron (SNP) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- GIMAP4 | c.58+39G>A | Intron (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- GIMAP4 | c.58+40G>A | Intron (SNP) | VAF 26/140 reads (19%) | catalogued as rs1285628200, COSV55433473; called by muse, mutect2, varscan2
- LINC01164 | n.913C>G | RNA (SNP) | VAF 56/272 reads (21%) | called by muse, mutect2, varscan2
- MSI2 | c.312+23740G>T | Intron (SNP) | VAF 25/187 reads (13%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.9327+477C>T | Intron (SNP) | VAF 120/348 reads (34%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.-40+11354G>T | Intron (SNP) | VAF 26/126 reads (21%) | called by muse, mutect2, varscan2
- SEC22C | c.183-177G>A | Intron (SNP) | VAF 38/189 reads (20%) | called by muse, mutect2, varscan2
- SNX15 | c.135+31C>T | Intron (SNP) | VAF 23/135 reads (17%) | catalogued as rs372669726; called by muse, mutect2, varscan2
- SNX9 | c.-30G>A | 5'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- SPEF2 | c.4448-2638C>A | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- SVEP1 | c.*32C>A | 3'UTR (SNP) | VAF 18/85 reads (21%) | called by muse, mutect2, varscan2
- TACC2 | c.5834+20287del | Intron (DEL) | VAF 17/128 reads (13%) | called by mutect2, pindel, varscan2
- ZNF451 | c.2752+42T>G | Intron (SNP) | VAF 18/81 reads (22%) | called by muse, mutect2, varscan2
